Somatic mutation profile of tumor specimen TCGA-AO-A0J6-01A (aliquot TCGA-AO-A0J6-01A-11W-A050-09) from TCGA case TCGA-AO-A0J6, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.5 years (22,462 days).
Specimen TCGA-AO-A0J6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6d74540-0a6b-4cd5-af29-c81ea0cdede3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A0J6-10A (Blood Derived Normal), aliquot TCGA-AO-A0J6-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c7bce42-d992-4385-9d39-820318920fb4

The open-access MAF lists 111 somatic variants for this specimen: 92 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 70, Silent 19, Frame Shift Del 9, Nonsense Mutation 6, Splice Site 3, In Frame Del 2, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP5 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV54536167; called by muse, mutect2
- ADGRE1 | c.2013C>A p.F671L | Missense Mutation (SNP) | VAF 170/431 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.022); catalogued as COSV51675135, COSV99165640; called by muse, mutect2, varscan2
- AHNAK | c.13649G>C p.G4550A | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.439); catalogued as COSV57212505; called by muse, mutect2, varscan2
- ARHGEF6 | c.1464T>A p.S488R | Missense Mutation (SNP) | VAF 112/196 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51690203; called by muse, mutect2, varscan2
- ARL11 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.34); PolyPhen benign (0.085); catalogued as COSV56290642; called by muse, mutect2, varscan2
- ATP1A3 | c.1838G>A p.G613D (on ENST00000545399 / NM_001256214.2; = p.G600D on NM_152296.5) | Missense Mutation (SNP) | VAF 88/241 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57487359; called by muse, mutect2, varscan2
- BPIFA2 | c.58T>C p.S20P | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.799); catalogued as COSV53610975; called by muse, mutect2, varscan2
- BRINP3 | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV100819037, COSV66523088; called by muse, mutect2, varscan2
- C1orf54 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.223); catalogued as COSV64257464; called by muse, mutect2, varscan2
- C9orf43 | c.1162A>C p.S388R | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV55912558; called by muse, mutect2, varscan2
- CES5A | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51866011, COSV99308157; called by muse, mutect2, varscan2
- CFAP54 | c.4755_4758del p.T1586Ffs*23 | Frame Shift Del (DEL) | VAF 65/147 reads (44%) | catalogued as rs1246585689; called by mutect2, pindel, varscan2
- CHRM1 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 71/209 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV61006623; called by muse, mutect2, varscan2
- CLUL1 | c.71G>C p.W24S | Missense Mutation (SNP) | VAF 82/279 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV100621039, COSV58111919; called by muse, mutect2, varscan2
- CNTLN | c.2704G>C p.D902H | Missense Mutation (SNP) | VAF 84/123 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV52076903; called by muse, mutect2, varscan2
- COX15 | c.586C>G p.L196V | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as COSV50012164; called by muse, mutect2, varscan2
- CYP2D6 | c.395_396insA p.R133Afs*121 | Frame Shift Ins (INS) | VAF 27/48 reads (56%) | catalogued as COSV62243913; called by mutect2, pindel, varscan2
- EIF2AK1 | c.1232-1G>A p.X411_splice | Splice Site (SNP) | VAF 25/84 reads (30%) | catalogued as COSV52238841; called by muse, mutect2, varscan2
- EPS8L1 | c.2139G>C p.K713N (on ENST00000201647 / NM_133180.3; = p.K586N on NM_017729.3) | Missense Mutation (SNP) | VAF 97/433 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV52381939; called by muse, mutect2, varscan2
- ETV3L | c.84C>G p.Y28* | Nonsense Mutation (SNP) | VAF 22/164 reads (13%) | catalogued as COSV71901048; called by muse, mutect2
- FAM53B | c.585C>A p.C195* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV55102179; called by muse, mutect2, varscan2
- FAM90A1 | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV56711903; called by muse, mutect2, varscan2
- FARP1 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.156); catalogued as rs142356955, COSV100130112; called by muse, mutect2, varscan2
- FBXO21 | c.1163T>C p.M388T | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57972662; called by muse, mutect2, varscan2
- FXR1 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 67/377 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59762747; called by muse, mutect2, varscan2
- GJB5 | c.690C>A p.H230Q | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV58356109; called by muse, mutect2, varscan2
- GRB2 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs371871562; called by muse, mutect2, varscan2
- HIVEP3 | c.4310G>T p.S1437I | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56014935; called by muse, mutect2, varscan2
- HSPA8 | c.1419G>C p.Q473H | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV57083824; called by muse, mutect2
- IFNE | c.181C>G p.L61V | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.495); catalogued as COSV58640535; called by muse, mutect2, varscan2
- INTS3 | c.1439A>T p.K480M | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59677385; called by muse, mutect2, varscan2
- IQCB1 | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 42/134 reads (31%) | catalogued as COSV60437269; called by muse, mutect2
- KLHDC3 | c.850A>C p.K284Q | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV55064181; called by muse, mutect2, varscan2
- KMT2D | c.9654_9664del p.L3220Wfs*9 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as COSV56436671; called by mutect2, pindel
- KRT19 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.103); catalogued as rs766547777, COSV54178819; called by muse, mutect2, varscan2
- LAMA2 | c.8511G>C p.M2837I | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.316); catalogued as COSV70346139; called by muse, mutect2, varscan2
- LRRC4B | c.1424G>T p.G475V | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV65349975; called by muse, mutect2, varscan2
- LTBP4 | c.4549G>T p.E1517* (on ENST00000308370 / NM_001042544.1; = p.E1480* on NM_003573.2) | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV52580908; called by muse, mutect2, varscan2
- MAP10 | c.1468C>G p.H490D | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV69363555; called by muse, mutect2, varscan2
- MED16 | c.915C>G p.I305M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as rs777459198, COSV54126099, COSV54129031; called by muse, mutect2, varscan2
- MPHOSPH9 | c.884C>T p.T295I | Missense Mutation (SNP) | VAF 108/168 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as rs995846178, COSV56619310; called by muse, mutect2, varscan2
- MRPL48 | c.518T>A p.I173K | Missense Mutation (SNP) | VAF 59/90 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV58638868, COSV58639135; called by muse, mutect2, varscan2
- MYO10 | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV72454129; called by muse, mutect2, varscan2
- NAP1L1 | c.374A>T p.Y125F | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.666); catalogued as COSV53874349; called by muse, mutect2, varscan2
- NECTIN2 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as COSV52977132; called by muse, mutect2, varscan2
- NGLY1 | c.1654T>C p.S552P | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54986004; called by muse, mutect2, varscan2
- NID1 | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV51619558; called by muse, mutect2, varscan2
- NR1D2 | c.1684C>T p.R562* | Nonsense Mutation (SNP) | VAF 51/76 reads (67%) | catalogued as rs1352385412, COSV56991577, COSV56992263; called by muse, mutect2, varscan2
- NSUN4 | c.688C>G p.Q230E | Missense Mutation (SNP) | VAF 84/314 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV61063091; called by muse, mutect2, varscan2
- OR10H4 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 183/596 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV59061786; called by muse, mutect2, varscan2
- OR51B4 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 85/256 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV66517180; called by muse, mutect2, varscan2
- OR52A5 | c.165C>G p.N55K | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV56615135; called by muse, mutect2, varscan2
- PHF3 | c.3562C>T p.R1188C | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs375919837; called by muse, mutect2, varscan2
- PI16 | c.1300G>C p.V434L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.012); catalogued as rs201227678, COSV65320472; called by muse, mutect2, varscan2
- PIK3C2B | c.3644G>A p.G1215D | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV65811189; called by muse, mutect2, varscan2
- PLK4 | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54637322; called by muse, mutect2, varscan2
- RANBP17 | c.1711G>T p.V571L | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV66649665; called by muse, mutect2, varscan2
- RASSF5 | c.1221G>C p.E407D | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV55113477; called by muse, mutect2, varscan2
- RHOB | c.37G>T p.D13Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55355794; called by muse, mutect2, varscan2
- RIMS1 | c.2608C>T p.H870Y | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs376554507; called by muse, mutect2, varscan2
- SCARB1 | c.652C>T p.L218F | Missense Mutation (SNP) | VAF 63/103 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs1234366562, COSV55547251; called by muse, mutect2, varscan2
- SCLT1 | c.1205C>T p.S402L | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as rs764679883, COSV55405368; called by muse, mutect2, varscan2
- SCN8A | c.4231A>C p.T1411P | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61981125; called by muse, mutect2, varscan2
- SEZ6L | c.735A>T p.K245N | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.162); catalogued as COSV50663115; called by muse, mutect2, varscan2
- SIRPB1 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 84/229 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.92); catalogued as COSV54375174; called by muse, mutect2, varscan2
- SLC12A5 | c.907G>T p.D303Y (on ENST00000454036 / NM_001134771.2; = p.D280Y on NM_020708.5) | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV54791546, COSV54793003; called by muse, mutect2, varscan2
- SLC45A4 | c.1982G>C p.G661A (on ENST00000517878 / NM_001286646.2; = p.G610A on NM_001080431.2) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50137854; called by muse, mutect2, varscan2
- SNN | c.126C>G p.S42R | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.928); catalogued as COSV51598802; called by muse, mutect2, varscan2
- SNX13 | c.548A>T p.D183V | Missense Mutation (SNP) | VAF 63/387 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV68064877; called by muse, mutect2, varscan2
- TAGLN2 | c.397G>C p.G133R | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57422187; called by muse, mutect2, varscan2
- TDRD5 | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV54242216, COSV99676316; called by muse, mutect2, varscan2
- TET3 | c.1130C>A p.T377N | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.127); catalogued as rs202078503, COSV59880837; called by muse, mutect2, varscan2
- TP53 | c.631del p.T211Lfs*36 | Frame Shift Del (DEL) | VAF 204/368 reads (55%) | catalogued as COSV52688982, COSV52795736, COSV52991157; called by mutect2, pindel, varscan2
- TTN | c.63753C>G p.N21251K (on ENST00000591111; = p.N13827K on NM_003319.4) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | PolyPhen benign (0.027); catalogued as COSV60033491; called by muse, mutect2, varscan2
- TUBA1B | c.346G>C p.D116H | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.792); catalogued as COSV60136923; called by muse, mutect2, varscan2
- TULP4 | c.4269C>A p.S1423R | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.238); catalogued as COSV65575041; called by muse, mutect2, varscan2
- UNC13A | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs560413297, COSV53194672; called by muse, mutect2, varscan2
- USF1 | c.276+2T>G p.X92_splice | Splice Site (SNP) | VAF 22/116 reads (19%) | catalogued as COSV99231341; called by muse, varscan2
- USH2A | c.7912A>C p.T2638P | Missense Mutation (SNP) | VAF 87/240 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56364541; called by muse, mutect2, varscan2
- WDR48 | c.934A>G p.I312V | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs774504800, COSV56531770; called by muse, mutect2, varscan2
- BCL9 | c.2523_2527delinsT p.R843Sfs*20 | Frame Shift Del (DEL) | VAF 45/192 reads (23%) | called by pindel, varscan2*
- DNAH10 | c.9211_9224del p.K3071Qfs*10 (on ENST00000409039; = p.K3010Qfs*10 on NM_207437.3) | Frame Shift Del (DEL) | VAF 33/59 reads (56%) | called by mutect2, pindel, varscan2
- FGFBP1 | c.210_220del p.W70* | Nonsense Mutation (DEL) | VAF 15/88 reads (17%) | called by mutect2, pindel, varscan2
- GRIA3 | c.1080+2_1080+16del p.X360_splice | Splice Site (DEL) | VAF 63/106 reads (59%) | called by mutect2, pindel, varscan2
- IGFL4 | c.98_105del p.A33Vfs*14 | Frame Shift Del (DEL) | VAF 68/222 reads (31%) | called by mutect2, pindel, varscan2
- IGKV1-5 | c.343A>C p.S115R | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PHF20L1 | c.2304_2331del p.I768Mfs*14 | Frame Shift Del (DEL) | VAF 40/162 reads (25%) | called by mutect2, pindel
- PLCB4 | c.251_256del p.E84_A85del | In Frame Del (DEL) | VAF 28/159 reads (18%) | called by mutect2, pindel, varscan2
- PTPN18 | c.917_919del p.I306del | In Frame Del (DEL) | VAF 25/67 reads (37%) | called by mutect2, pindel, varscan2
- SLC29A1 | c.134_173del p.M45Rfs*27 | Frame Shift Del (DEL) | VAF 33/119 reads (28%) | called by mutect2, pindel
- WWC3 | c.2218_2236del p.G740Pfs*18 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- ZNF484 | c.-12_12del | Translation Start Site (DEL) | VAF 44/244 reads (18%) | called by mutect2, pindel
- CFAP61 | c.2184T>C p.Y728= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as rs772626970, COSV55628111; called by muse, mutect2, varscan2
- CHRNA1 | c.621C>T p.S207= (on ENST00000261007 / NM_001039523.3; = p.S182= on NM_000079.4) | Silent (SNP) | VAF 58/137 reads (42%) | catalogued as rs749002411, COSV53682753; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL19A1 | c.225C>G p.T75= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1311910208, COSV59571852; called by muse, mutect2, varscan2
- DCP1A | c.1044G>A p.T348= | Silent (SNP) | VAF 55/115 reads (48%) | catalogued as rs376753632; called by muse, mutect2, varscan2
- DIO1 | c.621G>A p.Q207= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as COSV100498884, COSV59517856; called by muse, mutect2, varscan2
- DNAH9 | c.987G>A p.P329= | Silent (SNP) | VAF 36/57 reads (63%) | catalogued as rs200590483, COSV52348086; called by muse, mutect2, varscan2
- FRMD6 | c.1065G>C p.L355= (on ENST00000344768 / NM_001267046.2; = p.L347= on NM_152330.4) | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV61087817; called by muse, mutect2, varscan2
- LRP1B | c.5592A>G p.G1864= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as COSV67214744; called by muse, mutect2, varscan2
- NLRP12 | c.2763C>A p.G921= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV60746982; called by muse, mutect2
- NR4A3 | c.57G>A p.A19= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as rs765144422, COSV58244797; called by muse, mutect2, varscan2
- NXF3 | c.1455G>A p.L485= | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as COSV67703411; called by muse, mutect2, varscan2
- OBSCN | c.7521C>G p.P2507= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV52770835; called by muse, mutect2, varscan2
- SCARB2 | c.447G>A p.V149= | Silent (SNP) | VAF 42/63 reads (67%) | catalogued as COSV53668719; called by muse, mutect2, varscan2
- STX10 | c.165C>A p.R55= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs772865577, COSV52848057; called by muse, mutect2, varscan2
- SYNJ1 | c.141G>A p.R47= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV59147848; called by muse, mutect2, varscan2
- TCEANC2 | c.216C>A p.S72= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as COSV52369827; called by muse, mutect2, varscan2
- TEX47 | c.225A>T p.S75= | Silent (SNP) | VAF 70/210 reads (33%) | catalogued as COSV51878906; called by muse, mutect2, varscan2
- WIPF2 | c.30A>T p.P10= | Silent (SNP) | VAF 72/116 reads (62%) | catalogued as COSV60273630, COSV60275471; called by muse, mutect2, varscan2
- ZNF687 | c.1122C>G p.S374= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV55017139; called by muse, mutect2, varscan2
